Gene-level copy-number profile of tumor specimen TCGA-BR-6564-01A from TCGA case TCGA-BR-6564, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 46.9 years (17,129 days).
Specimen TCGA-BR-6564-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.4b67aad0-dee9-4ed2-b966-33fa6e565010.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-6564-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b1174d7e-a298-4243-9b16-d597a17f17d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,717; copy number 2: 38,164; copy number 3: 3,607; copy number 4: 2,002; copy number 5: 23; copy number 7: 76; copy number 9: 96; copy number 11: 49; copy number 12: 71; copy number 21: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-6564-01A-12D-1881-01): tumor purity 0.22, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 324 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:81,175,508–100,568,220, 321 genes, copy number 5–21 (broad region; genes not listed).
- chr18:22,347,846–22,419,294, 3 genes, copy number 5: AC027449.1, CTAGE1, ATP7BP1.

Autosomal genes at a single copy (total copy number 1): 15,717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
